Somatic mutation profile of tumor specimen MMRF_2522_1_BM_CD138pos (aliquot MMRF_2522_1_BM_CD138pos_T1_KHS5U_L13310) from MMRF case MMRF_2522, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.8 years (22,216 days).
Specimen MMRF_2522_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fece949c-8409-46df-92cb-7d3e0461a5fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2522_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2522_1_PB_Whole_C3_KHS5U_K15164; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/184a39e3-6294-44e1-bf62-d4c2f6dd126b

The open-access MAF lists 129 somatic variants for this specimen: 52 protein-altering or splice-affecting, 19 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 24, Silent 19, Intron 14, 5'UTR 13, 3'Flank 4, Splice Site 3, Nonsense Mutation 3, RNA 2, Frame Shift Ins 2, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 55/117 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121918453, CM013418, CM090463, COSV61004775, COSV61004869, COSV61006317; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- C1orf127 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs753672659; called by muse, mutect2, varscan2
- CCDC137 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.284); catalogued as rs751322931; called by muse, mutect2
- DMGDH | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs769817556, COSV54867957; called by muse, mutect2, varscan2
- EIF5 | c.11A>G p.N4S | Missense Mutation (SNP) | VAF 41/728 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs770491759; called by muse, mutect2
- FAM47B | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs374173252, COSV61457280; called by muse, mutect2, varscan2
- FAM71B | c.1474C>T p.R492* | Nonsense Mutation (SNP) | VAF 53/147 reads (36%) | catalogued as rs778276804, COSV57227961; called by muse, mutect2, varscan2
- FGF8 | c.644C>T p.P215L (on ENST00000344255 / NM_033164.4; = p.P197L on NM_006119.6) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs772602922; called by muse, mutect2, varscan2
- FRAS1 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs917920184, COSV99355018; called by muse, mutect2, varscan2
- FUBP1 | c.940+2T>G p.X314_splice | Splice Site (SNP) | VAF 84/88 reads (95%) | catalogued as COSV53936835; called by muse, mutect2, varscan2
- GRK7 | c.426G>C p.E142D | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs774557918; called by muse, mutect2, varscan2
- GRM4 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV65214328; called by muse, varscan2
- IGHV2-70 | c.151A>T p.S51C | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.368); catalogued as rs376400758; called by muse, varscan2
- IGHV2-70 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs373039668; called by muse, varscan2
- IGLV3-1 | c.118A>C p.T40P | Missense Mutation (SNP) | VAF 56/66 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as rs189772470; called by muse, varscan2
- KRTAP10-1 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs370416268; called by muse, mutect2, varscan2
- LDB3 | c.1654G>A p.G552S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.389); catalogued as rs771007816, COSV53938563, COSV53943564; called by muse, mutect2, varscan2
- OXNAD1 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 98/338 reads (29%) | catalogued as rs747587030; called by muse, mutect2, varscan2
- PDXP | c.362_373del p.E121_A124del | In Frame Del (DEL) | VAF 8/16 reads (50%) | catalogued as rs897458816; called by mutect2, varscan2
- PRR32 | c.379A>C p.N127H | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1006060581; called by muse, mutect2
- SVOP | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 73/158 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs963472116, COSV54466716; called by muse, mutect2, varscan2
- SZT2 | c.7142C>T p.A2381V (on ENST00000634258 / NM_001365999.1; = p.A2324V on NM_015284.4) | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100987045; called by muse, mutect2
- TDP2 | c.70A>G p.K24E | Missense Mutation (SNP) | VAF 362/571 reads (63%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs753545235; called by muse, mutect2, varscan2
- TOGARAM2 | c.2690G>A p.R897H | Missense Mutation (SNP) | VAF 63/90 reads (70%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs150801790, COSV65420236; called by muse, mutect2, varscan2
- CENPK | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 219/699 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- COL19A1 | c.1829T>G p.L610R | Missense Mutation (SNP) | VAF 105/174 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNMT1 | c.3450dup p.L1151Vfs*12 | Frame Shift Ins (INS) | VAF 65/216 reads (30%) | called by mutect2, pindel, varscan2
- FLI1 | c.792G>T p.Q264H | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- FSTL1 | c.509A>C p.K170T | Missense Mutation (SNP) | VAF 116/336 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- FYB1 | c.1759C>G p.P587A | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GOLGA2 | c.2398T>G p.F800V | Missense Mutation (SNP) | VAF 77/282 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ICE1 | c.202A>T p.N68Y | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- IGLV3-1 | c.38A>C p.Y13S | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IGLV3-1 | c.137dup p.L46Ffs*4 | Frame Shift Ins (INS) | VAF 38/52 reads (73%) | called by pindel, varscan2
- IGLV4-3 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IGLV4-69 | c.122C>G p.T41S | Missense Mutation (SNP) | VAF 80/174 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.289); called by muse, mutect2
- LNX1 | c.1255C>T p.R419* (on ENST00000263925 / NM_001126328.3; = p.R323* on NM_032622.2) | Nonsense Mutation (SNP) | VAF 59/201 reads (29%) | called by muse, mutect2, varscan2
- MAL2 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.078); called by muse, mutect2
- MYH14 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 67/227 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- NDST4 | c.239T>A p.V80D | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NFRKB | c.2585C>A p.T862N (on ENST00000446488 / NM_001143835.2; = p.T887N on NM_006165.3) | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- OR5T3 | c.836C>A p.A279D | Missense Mutation (SNP) | VAF 139/145 reads (96%) | SIFT deleterious (0.04); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- PIAS1 | c.1748A>T p.Y583F | Missense Mutation (SNP) | VAF 154/235 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- PKP4 | c.371C>G p.T124S | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXNC1 | c.2983+2T>C p.X995_splice | Splice Site (SNP) | VAF 48/110 reads (44%) | called by muse, mutect2, varscan2
- ROS1 | c.1604G>A p.S535N | Missense Mutation (SNP) | VAF 147/237 reads (62%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEL1L2 | c.1404+2T>C p.X468_splice | Splice Site (SNP) | VAF 46/124 reads (37%) | called by muse, mutect2, varscan2
- ULK4 | c.874A>G p.S292G | Missense Mutation (SNP) | VAF 11/289 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- ZNF233 | c.1419C>G p.I473M | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2
- ZNF233 | c.1421A>G p.H474R | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ZNF714 | c.409A>G p.T137A | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- ZNF717 | c.1771T>C p.Y591H | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.968); called by muse, mutect2
- CLEC4M | c.264A>G p.A88= | Silent (SNP) | VAF 78/300 reads (26%) | catalogued as rs1826305; called by muse, mutect2, varscan2
- CLIP2 | c.537G>A p.P179= | Silent (SNP) | VAF 57/114 reads (50%) | catalogued as rs1554732747; called by muse, mutect2, varscan2
- DNAH11 | c.5305C>T p.L1769= | Silent (SNP) | VAF 45/84 reads (54%) | catalogued as COSV60973709; called by muse, mutect2, varscan2
- DNAH2 | c.9276G>T p.L3092= | Silent (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- EPN1 | c.1599C>G p.L533= (on ENST00000270460 / NM_001321263.1; = p.L507= on NM_013333.3) | Silent (SNP) | VAF 61/314 reads (19%) | catalogued as COSV99322540; called by muse, mutect2, varscan2
- IGHV2-70 | c.168C>T p.S56= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as rs367953381; called by muse, varscan2
- IGHV2-70 | c.96A>G p.K32= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs368957766; called by muse, varscan2
- NCBP2L | c.375C>T p.R125= | Silent (SNP) | VAF 131/407 reads (32%) | catalogued as rs773993102, COSV64943883; called by muse, mutect2, varscan2
- NDST4 | c.240C>A p.V80= | Silent (SNP) | VAF 47/179 reads (26%) | called by muse, mutect2, varscan2
- PADI2 | c.660G>A p.P220= | Silent (SNP) | VAF 53/106 reads (50%) | catalogued as rs770453434; called by muse, mutect2, varscan2
- PCDHA6 | c.1815G>A p.A605= | Silent (SNP) | VAF 43/124 reads (35%) | catalogued as rs782737913; called by muse, mutect2, varscan2
- PGPEP1L | c.453G>A p.S151= | Silent (SNP) | VAF 49/116 reads (42%) | catalogued as rs747165092, COSV51324930; called by muse, mutect2, varscan2
- SEBOX | c.531C>T p.L177= | Silent (SNP) | VAF 14/202 reads (7%) | called by muse, mutect2
- SEMA3A | c.165C>T p.S55= | Silent (SNP) | VAF 70/168 reads (42%) | called by muse, mutect2, varscan2
- SEMA6D | c.1038A>G p.E346= | Silent (SNP) | VAF 140/227 reads (62%) | called by muse, mutect2, varscan2
- SSTR1 | c.702G>A p.L234= | Silent (SNP) | VAF 9/128 reads (7%) | called by muse, mutect2
- TENM2 | c.825G>A p.L275= (on ENST00000518659 / NM_001122679.2; = p.L84= on NM_001080428.3) | Silent (SNP) | VAF 69/249 reads (28%) | called by muse, mutect2, varscan2
- TLE6 | c.1209C>A p.V403= (on ENST00000246112 / NM_001143986.2; = p.V280= on NM_024760.3) | Silent (SNP) | VAF 44/124 reads (35%) | called by muse, mutect2
- VCP | c.1539A>C p.G513= | Silent (SNP) | VAF 26/83 reads (31%) | called by muse, mutect2, varscan2
- ABCG4 | c.1168-29T>C | Intron (SNP) | VAF 92/222 reads (41%) | called by muse, mutect2, varscan2
- ADARB2 | c.101-147669C>T | Intron (SNP) | VAF 26/60 reads (43%) | catalogued as COSV101184476, COSV101184498; called by muse, mutect2, varscan2
- ARL15 | c.-36G>A | 5'UTR (SNP) | VAF 99/337 reads (29%) | called by mutect2, varscan2
- ARMCX4 | c.1038+3927G>A | Intron (SNP) | VAF 42/140 reads (30%) | catalogued as rs1355351430; called by muse, mutect2, varscan2
- BCL7A | chr12:122021658 A>T | 5'Flank (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- BMP6 | c.*941dup | 3'UTR (INS) | VAF 34/111 reads (31%) | called by mutect2, pindel, varscan2
- BRWD1 | c.-118_-117del | 5'UTR (DEL) | VAF 12/40 reads (30%) | called by mutect2, varscan2
- C15orf62 | c.-283T>G | 5'UTR (SNP) | VAF 52/212 reads (25%) | called by mutect2, varscan2
- C9orf57 | c.*88A>G | 3'UTR (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- CCDC160 | chrX:134246139 C>T | 3'Flank (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- CDX2 | c.-164C>T | 5'UTR (SNP) | VAF 16/17 reads (94%) | called by muse, mutect2, varscan2
- CEP152 | c.4093+64C>T | Intron (SNP) | VAF 119/389 reads (31%) | catalogued as rs745508471, COSV100358869; called by muse, mutect2, varscan2
- CEP44 | c.1086+110C>T | Intron (SNP) | VAF 14/14 reads (100%) | called by muse, mutect2, varscan2
- COL4A5 | c.3791-2800T>A | Intron (SNP) | VAF 56/184 reads (30%) | called by muse, mutect2, varscan2
- COMMD6 | c.54+139T>C | Intron (SNP) | VAF 27/28 reads (96%) | called by muse, mutect2, varscan2
- DAPL1 | c.*49C>T | 3'UTR (SNP) | VAF 157/358 reads (44%) | catalogued as rs752008830; called by muse, mutect2, varscan2
- DDX41 | c.*720C>T | 3'UTR (SNP) | VAF 55/174 reads (32%) | catalogued as rs1420919289; called by muse, mutect2, varscan2
- EGLN3 | c.-79G>A | 5'UTR (SNP) | VAF 34/86 reads (40%) | called by muse, mutect2, varscan2
- ELOVL3 | c.*175del | 3'UTR (DEL) | VAF 17/46 reads (37%) | called by mutect2, pindel, varscan2
- FBXW2 | c.*280T>C | 3'UTR (SNP) | VAF 46/145 reads (32%) | called by muse, mutect2, varscan2
- HDX | c.*1058C>G | 3'UTR (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- HMGN3 | c.-20G>A | 5'UTR (SNP) | VAF 90/265 reads (34%) | called by muse, mutect2, varscan2
- HYPK | c.-4007G>C | 5'UTR (SNP) | VAF 7/110 reads (6%) | called by muse, mutect2
- ICOS | c.*1478G>A | 3'UTR (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- IGHV4-39 | c.-25A>G | 5'UTR (SNP) | VAF 23/40 reads (58%) | catalogued as rs1265854253; called by muse, mutect2, varscan2
- IRS1 | c.-262T>A | 5'UTR (SNP) | VAF 89/99 reads (90%) | called by muse, mutect2, varscan2
- KLHL4 | c.*597G>A | 3'UTR (SNP) | VAF 15/44 reads (34%) | catalogued as rs1054290519; called by muse, mutect2
- KLKP1 | n.323_325del | RNA (DEL) | VAF 11/16 reads (69%) | called by mutect2, varscan2
- LPP | c.1240+2545A>G | Intron (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- MIR363 | chrX:134169292 T>G | 3'Flank (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2
- MSL3 | c.*137G>T | 3'UTR (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- MYO1E | c.-116G>T | 5'UTR (SNP) | VAF 66/107 reads (62%) | called by muse, mutect2, varscan2
- MYOZ2 | c.*612A>G | 3'UTR (SNP) | VAF 19/66 reads (29%) | called by muse, mutect2, varscan2
- NACC2 | c.*200C>A | 3'UTR (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- NHSL1 | c.203-3094T>A | Intron (SNP) | VAF 33/101 reads (33%) | called by muse, mutect2, varscan2
- NKX2-4 | c.-53C>T | 5'UTR (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- PAIP2B | c.*4997G>A | 3'UTR (SNP) | VAF 39/42 reads (93%) | called by mutect2, varscan2
- PCDH19 | c.*1480T>G | 3'UTR (SNP) | VAF 29/93 reads (31%) | called by muse, mutect2, varscan2
- PGGT1B | c.*1491T>A | 3'UTR (SNP) | VAF 89/276 reads (32%) | called by muse, mutect2, varscan2
- PPP1CB | c.-81G>C | 5'UTR (SNP) | VAF 47/143 reads (33%) | called by muse, mutect2, varscan2
- REC8 | c.865-105A>G | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, varscan2
- RIMS3 | chr1:40621513 G>A | 3'Flank (SNP) | VAF 47/48 reads (98%) | catalogued as rs778923600; called by muse, mutect2, varscan2
- SH3BGRL2 | c.*4028C>T | 3'UTR (SNP) | VAF 27/134 reads (20%) | called by muse, mutect2, varscan2
- SLC13A1 | c.*1040A>G | 3'UTR (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- SLC2A13 | c.*2042A>G | 3'UTR (SNP) | VAF 8/20 reads (40%) | catalogued as rs1472407324; called by muse, mutect2
- SLC6A14 | c.*1031A>G | 3'UTR (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- SMIM13 | chr6:11137973 A>T | 3'Flank (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2, varscan2
- STK4 | c.*1170A>G | 3'UTR (SNP) | VAF 48/121 reads (40%) | called by muse, mutect2
- TBC1D20 | c.*1198G>A | 3'UTR (SNP) | VAF 32/86 reads (37%) | called by mutect2, varscan2
- TBRG4 | c.412-486A>G | Intron (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- TMEM150C | c.363+25T>G | Intron (SNP) | VAF 57/204 reads (28%) | called by muse, mutect2, varscan2
- TMSB4X | c.-49C>T | 5'UTR (SNP) | VAF 48/93 reads (52%) | catalogued as COSV66081669; called by muse, mutect2, varscan2
- TMSB4X | c.-17+229T>A | Intron (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- TTC23 | c.*1447C>T | 3'UTR (SNP) | VAF 27/81 reads (33%) | catalogued as rs1449018030; called by muse, mutect2, varscan2
- WNT7B | c.71+4297C>T | Intron (SNP) | VAF 6/9 reads (67%) | called by muse, mutect2
- ZNF275 | c.*2796A>T | 3'UTR (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- ZNF286B | n.4343T>G | RNA (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- ZYX | c.*388G>A | 3'UTR (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2, varscan2
